Gene-level copy-number profile of tumor specimen TCGA-HB-A3L4-01A from TCGA case TCGA-HB-A3L4, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Uterus, NOS; Age at diagnosis: 46.7 years (17,044 days).
Specimen TCGA-HB-A3L4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.309737bf-aeeb-4f88-9042-e62cc52df00f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HB-A3L4-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/fd51647f-0da2-43c6-b4c0-e08ff50d96ce

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 51; copy number 1: 13,025; copy number 2: 41,544; copy number 3: 4,636; copy number 4: 131; copy number 5: 84; copy number 6: 343.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HB-A3L4-01A-11D-A21P-01): tumor purity 0.98, ploidy 1.85, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 51 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:84,720,826–85,021,655, 6 genes: AP001825.1, AP001825.2, AP001825.3, AP000857.2, AP000857.1, HNRNPCP6.
- chr13:21,260,015–21,604,181, 13 genes: ESRRAP2, AL158032.2, MIPEPP3, LINC00539, GRK6P1, GAPDHP52, RNA5SP25, ZDHHC20, ZDHHC20-IT1, H2BP6, MICU2, FNTAP2, RNU6-59P.
- chr13:23,954,493–24,321,031, 5 genes (within-gene range 0–1): AL445985.2, AL359736.1, SPATA13, AL445985.1, IPO7P2.
- chr13:31,134,973–31,332,276, 3 genes: HSPH1, B3GLCT, ANKRD26P4.
- chr13:32,303,699–32,778,019, 11 genes: ZAR1L, BRCA2, IFIT1P1, N4BP2L1, AL137247.1, AL137247.2, N4BP2L2, ATP8A2P2, N4BP2L2-IT2, PDS5B, RNY1P4.
- chr13:33,158,587–33,164,409, 1 gene: STARD13-IT1.
- chr13:48,296,162–48,599,436, 7 genes (within-gene range 0–1): RB1-DT, RB1, PPP1R26P1, PCNPP5, AL392048.1, LPAR6, Metazoa_SRP.
- chr13:48,974,967–49,209,779, 5 genes (within-gene range 0–1): AL161421.1, FNDC3A, RNU6-60P, RAD17P2, RNY3P2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 427 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:247,920,252–248,919,946, 60 genes, copy number 5: OR2T8, OR2AJ1, CLK3P2, OR2X1P, OR2L8, OR2AK2, OR2L9P, OR2L1P, Y_RNA, OR2L6P, OR2L5, Y_RNA, OR2L2, Y_RNA, OR2L3, OR2T32P, OR2L13, OR2M1P, OR2M5, OR2M2, OR2M3, OR2M4, OR2T33, OR2T12, OR2M7, OR14C36, OR2T4, OR2T6, OR2T1, OR2T7, OR2T2, OR2T3, AC138089.1, OR2T5, OR2AS2P, OR2G6, AC098483.1, OR2AS1P, OR2T29, OR2T34, OR2T10, Y_RNA, AC098483.2, OR2T11, OR2T35, OR2T27, CR589904.2, OR14I1, LYPD9P, CR589904.1, AHCYP8, LYPD8, DPY19L4P1, SH3BP5L, MIR3124, ZNF672, ZNF692, AL672291.1, PGBD2, RNU6-1205P.
- chr9:68,328,308–68,531,061, 1 gene, copy number 6 (within-gene range 2–6): PGM5.
- chr9:68,426,843–70,354,873, 33 genes, copy number 5–6 (within-gene range 2–6): AL161457.1, TMEM252, TMEM252-DT, LINC01506, AL353616.1, PIP5K1B, FAM122A, AL354794.2, AL354794.1, RNU6-820P, PRKACG, AL358113.1, FXN, AL162730.1, TJP2, BANCR, FAM189A2, APBA1, AL355140.1, AL353693.1, AL162412.1, PTAR1, C9orf135-DT, C9orf135, RN7SL570P, MAMDC2-AS1, MAMDC2, RNU2-5P, SMC5-AS1, RPL24P8, SMC5, AL162390.1, Y_RNA.
- chr9:73,474,378–73,873,297, 6 genes, copy number 5: DPP3P2, AL451127.2, AL451127.1, AL512594.1, RNA5SP286, AL513124.1.
- chr9:77,177,445–77,648,322, 5 genes, copy number 5 (within-gene range 3–5): VPS13A, GNA14, GNA14-AS1, NUTF2P3, RNU6-1303P.
- chr9:79,135,374–80,360,338, 12 genes, copy number 6: AL512634.1, CHCHD2P9, LNCARSR, TLE4, AL161912.3, NPAP1P6, AL161912.1, AL161912.2, AL161912.4, AL161782.1, LINC01507, NPAP1P4.
- chr9:83,739,425–95,426,796, 239 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).
- chr9:113,038,377–117,415,070, 71 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 12,914. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
